Gene-level copy-number profile of tumor specimen TCGA-69-7974-01A from TCGA case TCGA-69-7974, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.8 years (20,021 days).
Specimen TCGA-69-7974-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.21fbe471-d198-41cf-a2dc-16c46996fac5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7974-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f2ff4bf-4f2c-4923-8b13-ed777c5626ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 6,565; copy number 3: 22,479; copy number 4: 21,372; copy number 5: 635; copy number 6: 3,757; copy number 7: 2,659; copy number 8: 79; copy number 9: 2,267; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7974-01A-11D-2183-01): tumor purity 0.29, ploidy 3.55, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,936,079–9,442,380, 3 genes: AL596451.1, RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,008 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,262,023, 79 genes, copy number 8 (broad region; genes not listed).
- chr5:3,177,835–30,693,984, 368 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr5:107,376,889–107,670,937, 1 gene, copy number 7 (within-gene range 3–7): EFNA5.
- chr11:37,702,125–135,075,908, 2,440 genes, copy number 7 (broad region; genes not listed).
- chr14:62,514,872–62,605,717, 2 genes, copy number 7: AL389895.1, ATP5F1AP4.
- chr17:27,002,661–83,095,122, 2,118 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
